Gene-level copy-number profile of tumor specimen TCGA-D1-A17K-01A from TCGA case TCGA-D1-A17K, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 74.7 years (27,283 days).
Specimen TCGA-D1-A17K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.3201128d-0764-462c-a2cf-dde84359dc0c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D1-A17K-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/865c06df-b81a-4615-80e0-f9691eed3b0e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 1: 12,924; copy number 2: 43,219; copy number 3: 3,043; copy number 4: 330; copy number 5: 87; copy number 6: 134; copy number 8: 2; copy number 14: 13; copy number 21: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D1-A17K-01A-11D-A12G-01): tumor purity 0.92, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 29 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,859,158–88,994,249, 24 genes: KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3.
- chr10:88,992,370–88,992,539, 1 gene: AL157394.2.
- chr22:28,794,555–28,848,559, 4 genes: XBP1, Z93930.2, Z93930.3, Z93930.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 271 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:15,166,914–27,988,087, 249 genes, copy number 5–21 (within-gene range 3–21) (broad region; genes not listed).
- chr2:27,896,116–27,897,195, 1 gene, copy number 5: MYG1P1.
- chr5:151,770,242–151,812,911, 2 genes, copy number 8: AC091982.3, G3BP1.
- chr15:71,547,280–71,549,832, 1 gene, copy number 5: AC108861.1.
- chr15:84,980,440–85,749,358, 18 genes, copy number 6 (within-gene range 3–6): PDE8A, AC044860.2, AC044860.1, NIFKP8, CSPG4P12, RN7SL428P, GOLGA6L3, ADAMTS7P4, AC044860.3, AKAP13, MIR7706, RNU7-79P, FABP5P9, AC087286.3, AC087286.2, AC087286.1, RNU6-1280P, AC087286.4.

Autosomal genes at a single copy (total copy number 1): 12,924. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
